FM case AD108 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Bronchus and lung.
https://portal.gdc.cancer.gov/cases/10deb9cc-c3bc-48f2-991b-64c7f39dc043

Male, 20.2 years: Atypical carcinoid tumor (ICD-O-3 8249/3) of the lung; primary biopsied or resected from the lung. Tumor nuclei on the sequenced sample's slide: 90% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
